Somatic mutation profile of tumor specimen ALCH-B2QD-TTP1-A (aliquot ALCH-B2QD-TTP1-A-8-0-D-A77Z-36) from ALCHEMIST case ALCH-B2QD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.6 years (29,075 days).
Specimen ALCH-B2QD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38f138f7-3ddd-4bdd-80c4-e4c32ceb0301.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QD-NB1-A (Blood Derived Normal), aliquot ALCH-B2QD-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29765139-3ae7-418a-b1dd-78307ee67730

The open-access MAF lists 189 somatic variants for this specimen: 138 protein-altering or splice-affecting, 30 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 30, Intron 9, Nonsense Mutation 9, RNA 7, Splice Site 6, 5'Flank 2, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/285 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BARD1 | c.2271G>T p.K757N | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1064796724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTRL | c.1729C>A p.R577S | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748020948; called by muse, mutect2
- CPS1 | c.2073G>T p.L691F | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV99242249; called by muse, varscan2
- CSMD1 | c.7451G>A p.W2484* (on ENST00000520002; = p.W2483* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV59375332; called by muse, mutect2, varscan2
- CSMD3 | c.10004G>T p.G3335V (on ENST00000297405 / NM_001363185.1; = p.G3166V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52224909; called by muse, mutect2, varscan2
- CTCFL | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54777732; called by muse, mutect2, varscan2
- CTNNA3 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65524929; called by muse, varscan2
- DHCR7 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs757861528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.2332C>A p.Q778K | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as CM115768; called by muse, mutect2, varscan2
- DNAH9 | c.12540C>A p.H4180Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183066755; called by muse, mutect2, varscan2
- DNAJC21 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 46/451 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as COSV100331309; called by muse, mutect2
- DYSF | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 131/756 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs770228554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYS | c.6344A>G p.H2115R | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1046447869, COSV101010013; called by muse, mutect2, varscan2
- F13B | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803395; called by muse, mutect2, varscan2
- FGD1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs867793721; called by muse, mutect2, varscan2
- FH | c.778A>T p.T260S | Missense Mutation (SNP) | VAF 11/323 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100844992; called by muse, mutect2
- GRIPAP1 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 77/440 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs1557062791; called by muse, mutect2, varscan2
- KLKB1 | c.1205G>T p.W402L | Missense Mutation (SNP) | VAF 100/588 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM033393; called by muse, mutect2, varscan2
- LHX8 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99634435; called by muse, mutect2, varscan2
- LOXHD1 | c.4740G>C p.K1580N | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56069711; called by muse, mutect2, varscan2
- MAGEE1 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs782677785, COSV100819446; called by muse, mutect2, varscan2
- MCF2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747639067, COSV58492945; called by muse, mutect2, varscan2
- MUC16 | c.39256C>A p.H13086N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs770063631, COSV66695589, COSV66696469; called by muse, varscan2
- MYT1L | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs774451946, COSV67707093; called by muse, mutect2
- NEU4 | c.26G>A p.R9Q (on ENST00000391969 / NM_001167602.3; = p.R21Q on NM_080741.4) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs138212045; called by muse, mutect2, varscan2
- OR5D13 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs753838527, COSV62334387; called by muse, mutect2, varscan2
- OR5D18 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61736601; called by muse, mutect2
- P4HTM | c.1303G>A p.V435I (on ENST00000383729 / NM_177939.3; = p.V496I on NM_177938.2) | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as rs935593731; called by muse, mutect2, varscan2
- PAM | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as rs1211372636; called by muse, mutect2, varscan2
- PCDHB12 | c.1802G>T p.W601L | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV53401555; called by muse, mutect2, varscan2
- PCDHB5 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 111/702 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs782009059, COSV50679708; called by muse, mutect2, varscan2
- PCSK5 | c.2560A>G p.T854A | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1301987564; called by muse, mutect2
- PKD1L3 | c.2095G>T p.V699F | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs370868068; called by muse, mutect2, varscan2
- PPP1R18 | c.1157A>T p.Q386L | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs757821931; called by muse, mutect2, varscan2
- RTCA | c.511C>G p.R171G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV53120064; called by muse, mutect2, varscan2
- TIAM2 | c.4600G>A p.E1534K (on ENST00000529824; = p.E1505K on NM_012454.3) | Missense Mutation (SNP) | VAF 93/487 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.766); catalogued as rs749703631, COSV51639924; called by muse, mutect2, varscan2
- UGT1A7 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 83/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60852795; called by muse, mutect2, varscan2
- ZNF143 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV100217831; called by muse, mutect2, varscan2
- ZNF304 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs755712483; called by muse, mutect2, varscan2
- ZNF786 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs201590585; called by muse, mutect2, varscan2
- ZNF831 | c.3440G>T p.W1147L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64046985; called by muse, mutect2, varscan2
- ACIN1 | c.115T>C p.W39R | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ACSS1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFAP1 | c.2143G>C p.G715R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ALPK2 | c.922T>A p.Y308N | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ANO2 | c.2561G>T p.S854I (on ENST00000356134 / NM_001278597.3; = p.S858I on NM_001278596.3) | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C16orf78 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1H | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 127/494 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKK1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.11617G>T p.V3873L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC168 | c.11616G>T p.E3872D | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CD44 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CDCP2 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, varscan2
- CDHR3 | c.2304+1G>A p.X768_splice | Splice Site (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- CERS5 | c.1066T>A p.S356T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CHD8 | c.1393G>C p.V465L (on ENST00000646647 / NM_001170629.2; = p.V186L on NM_020920.4) | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CNKSR2 | c.1633C>A p.H545N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COG1 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 114/619 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPS1 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | called by muse, varscan2
- DDB1 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1A | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DNMT3A | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DSG3 | c.372+1G>A p.X124_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- ELAPOR2 | c.1366A>T p.N456Y (on ENST00000450689 / NM_001142749.3; = p.N289Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, varscan2
- ERMARD | c.1854-1G>C p.X618_splice | Splice Site (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- EZHIP | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FAM133A | c.174A>C p.L58F | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTKD2 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FZD10 | c.530C>A p.A177E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GABRG2 | c.1399G>T p.G467* (on ENST00000361925 / NM_001375343.1; = p.G427* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/353 reads (15%) | called by muse, mutect2, varscan2
- GALNTL6 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- GAS2L2 | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GAS7 | c.829C>G p.Q277E (on ENST00000432992 / NM_201433.2; = p.Q137E on NM_003644.3) | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HDGFL1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 73/403 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.8130G>C p.K2710N | Missense Mutation (SNP) | VAF 114/379 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFNA5 | c.319A>T p.K107* | Nonsense Mutation (SNP) | VAF 32/237 reads (14%) | called by muse, mutect2, varscan2
- IFT140 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 70/506 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- IGKV2D-28 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by mutect2, varscan2
- KCNJ16 | c.1255T>C p.*419Qext*2 | Nonstop Mutation (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- KLHL4 | c.925-1G>T p.X309_splice | Splice Site (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- KRT222 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- LAMA2 | c.6830C>T p.A2277V | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIFR | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LILRB4 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- LTBP1 | c.3780T>A p.C1260* (on ENST00000404816 / NM_206943.4; = p.C934* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- LY6H | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAGEL2 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MORC4 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MUC16 | c.33310A>T p.S11104C | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MYO18B | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MYO7B | c.2536T>C p.Y846H | Missense Mutation (SNP) | VAF 81/474 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- NAV3 | c.7098C>G p.D2366E (on ENST00000397909 / NM_001024383.2; = p.D2344E on NM_014903.6) | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NETO1 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NF1 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUP98 | c.3926G>T p.W1309L (on ENST00000359171 / NM_001365126.1; = p.W1292L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR1F1 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- P2RY4 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDHGB3 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PCLO | c.7957G>T p.V2653F | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE1B | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PEG3 | c.4234G>C p.E1412Q | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLAA | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- PLEKHS1 | c.184C>G p.R62G (on ENST00000369310 / NM_182601.1; = p.R68G on NM_024889.5) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PPP1CC | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R3A | c.2118dup p.E707Rfs*6 | Frame Shift Ins (INS) | VAF 41/310 reads (13%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.1863T>A p.H621Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PPP4R3C | c.1861C>A p.H621N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.111); called by muse, mutect2
- RP1L1 | c.5935G>T p.A1979S | Missense Mutation (SNP) | VAF 120/472 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RTL3 | c.734G>T p.S245I | Missense Mutation (SNP) | VAF 152/518 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- RYR2 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RYR2 | c.10000G>T p.V3334L | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SGIP1 | c.1026C>G p.N342K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SH3TC2 | c.3613G>T p.E1205* | Nonsense Mutation (SNP) | VAF 66/346 reads (19%) | called by muse, mutect2, varscan2
- SLC22A15 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SLC9A4 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SLITRK4 | c.2141C>A p.P714H | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMARCA4 | c.3482T>G p.L1161R | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMCR8 | c.2301G>C p.W767C | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SYNE1 | c.24674_24692del p.R8225Tfs*101 (on ENST00000367255 / NM_182961.4; = p.R8154Tfs*97 on NM_033071.3) | Frame Shift Del (DEL) | VAF 34/239 reads (14%) | called by mutect2, pindel, varscan2
- SYT10 | c.1529G>T p.S510I | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SYTL4 | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF3 | c.2606C>G p.P869R | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAS2R41 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 88/549 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TENM3 | c.2692C>A p.R898S | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- TEX11 | c.2667G>T p.W889C (on ENST00000344304; = p.W874C on NM_031276.3) | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TIE1 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMEM130 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TNRC6C | c.211del p.D71Mfs*7 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- TRIM51GP | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 34/272 reads (13%) | called by muse, mutect2, varscan2
- TRPA1 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSHZ2 | c.2975C>A p.S992Y | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- TSPAN8 | c.240A>C p.E80D | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VN1R2 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VSTM1 | c.51C>G p.Y17* | Nonsense Mutation (SNP) | VAF 25/177 reads (14%) | called by muse, varscan2
- WDFY4 | c.4051G>T p.A1351S | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF578 | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZW10 | c.421-1G>T p.X141_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- ABCC2 | c.2575C>T p.L859= | Silent (SNP) | VAF 55/329 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.136C>A p.R46= | Silent (SNP) | VAF 42/274 reads (15%) | called by muse, mutect2, varscan2
- ADD3 | c.498T>C p.S166= | Silent (SNP) | VAF 36/176 reads (20%) | called by muse, varscan2
- ANKS1B | c.864G>T p.V288= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV61381193; called by muse, mutect2, varscan2
- ARHGAP22 | c.513G>T p.L171= | Silent (SNP) | VAF 57/411 reads (14%) | catalogued as COSV50932420, COSV50957649; called by muse, mutect2, varscan2
- CD99L2 | c.699C>A p.A233= | Silent (SNP) | VAF 39/373 reads (10%) | catalogued as COSV60936551; called by muse, mutect2, varscan2
- CFAP65 | c.3450C>A p.T1150= | Silent (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2
- COL13A1 | c.1581A>T p.G527= (on ENST00000398978 / NM_001130103.2; = p.G470= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- EEF2 | c.2139C>T p.A713= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- GLYATL3 | c.723G>T p.R241= | Silent (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- HCN3 | c.1317A>T p.A439= | Silent (SNP) | VAF 58/402 reads (14%) | called by muse, mutect2, varscan2
- HOXD13 | c.180G>T p.A60= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- INTS1 | c.3489C>T p.H1163= | Silent (SNP) | VAF 38/229 reads (17%) | catalogued as rs1341635746; called by muse, mutect2, varscan2
- IRS1 | c.828C>T p.C276= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs750624110; called by muse, mutect2, varscan2
- KIAA0100 | c.5838T>C p.D1946= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1223801702; called by muse, mutect2, varscan2
- MAGEC3 | c.57C>A p.G19= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- MEPE | c.639C>A p.T213= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- MGAT4A | c.1197C>T p.S399= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- OPN1SW | c.570C>A p.T190= | Silent (SNP) | VAF 68/361 reads (19%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.894G>T p.L298= | Silent (SNP) | VAF 26/261 reads (10%) | called by muse, mutect2, varscan2
- PDE3A | c.175C>A p.R59= | Silent (SNP) | VAF 47/266 reads (18%) | catalogued as COSV62972908; called by muse, mutect2, varscan2
- PLXNA4 | c.4008G>A p.R1336= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV58123253; called by mutect2, varscan2
- POTEJ | c.2880A>T p.T960= | Silent (SNP) | VAF 76/961 reads (8%) | called by muse, mutect2, varscan2
- PRR27 | c.21C>A p.A7= | Silent (SNP) | VAF 40/281 reads (14%) | called by muse, mutect2, varscan2
- RBL1 | c.669A>T p.L223= | Silent (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- RP1L1 | c.5934G>A p.E1978= | Silent (SNP) | VAF 117/468 reads (25%) | called by muse, mutect2, varscan2
- STAU2 | c.243G>A p.K81= (on ENST00000524300 / NM_001164380.2; = p.K49= on NM_014393.2) | Silent (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- TIAM1 | c.1101C>A p.G367= | Silent (SNP) | VAF 147/633 reads (23%) | called by muse, mutect2, varscan2
- TTI2 | c.45T>C p.S15= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV62452467; called by muse, mutect2, varscan2
- VN1R5 | c.735A>T p.T245= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- ACTR3BP2 | n.785C>A | RNA (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- APLP2 | c.105+517C>T | Intron (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+5067G>T | Intron (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- CHTF18 | chr16:788308 C>T | 5'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, varscan2
- CLASP1 | c.196-639T>A | Intron (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- DCHS2 | n.5607C>G | RNA (SNP) | VAF 22/165 reads (13%) | catalogued as COSV61777179; called by muse, mutect2, varscan2
- DCHS2 | n.5606G>T | RNA (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- FLJ42393 | n.901C>T | RNA (SNP) | VAF 64/318 reads (20%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16534A>G | Intron (SNP) | VAF 30/251 reads (12%) | called by muse, mutect2, varscan2
- KRT18 | c.-22C>G | 5'UTR (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- LEPROT | chr1:65420643 G>T | 5'Flank (SNP) | VAF 42/237 reads (18%) | called by muse, varscan2
- LIG3 | c.*736_*753del | 3'UTR (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel*
- NECTIN3-AS1 | n.1072C>A | RNA (SNP) | VAF 63/318 reads (20%) | called by muse, mutect2, varscan2
- NKAIN4 | c.618-227C>A | Intron (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- OR52Z1 | n.368C>A | RNA (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- PTCH1 | c.3450-33A>T | Intron (SNP) | VAF 56/315 reads (18%) | called by muse, mutect2, varscan2
- SH3GL3 | c.-64G>A | 5'UTR (SNP) | VAF 31/135 reads (23%) | catalogued as COSV61059849; called by muse, mutect2, varscan2
- SIGLEC12 | c.428-16C>G | Intron (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- TYK2 | c.2908+28A>T | Intron (SNP) | VAF 25/177 reads (14%) | catalogued as rs377141021; called by muse, mutect2, varscan2
- UGT1A6 | c.862-12003C>T | Intron (SNP) | VAF 57/271 reads (21%) | called by muse, mutect2, varscan2
- ZNF849P | n.1279C>A | RNA (SNP) | VAF 53/336 reads (16%) | called by muse, varscan2
